Somatic mutation profile of tumor specimen TARGET-30-PARDIW-01A (aliquot TARGET-30-PARDIW-01A-01D) from TARGET case TARGET-30-PARDIW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.6 years (2,048 days).
Specimen TARGET-30-PARDIW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af54e899-c549-4f39-99a1-5ba112f67f3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARDIW-10A (Blood Derived Normal), aliquot TARGET-30-PARDIW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2cb8480-8d05-442c-9d03-d1738d46846b

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6A | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs763908797, COSV66998724; called by muse, mutect2, varscan2
- CDYL | c.341C>T p.T114M (on ENST00000328908 / NM_001368125.1; = p.T60M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs766462758, COSV59358506; called by muse, mutect2, varscan2
- FBN2 | c.5523C>A p.Y1841* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as COSV52496512; called by muse, mutect2, varscan2
- HDLBP | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1180226952, COSV60492576; called by muse, mutect2, varscan2
- HECW1 | c.4490A>G p.N1497S | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV67823545; called by muse, mutect2, varscan2
- MUC17 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs761973973, COSV60281736; called by muse, mutect2, varscan2
- PHRF1 | c.2482G>A p.E828K (on ENST00000264555 / NM_001286581.2; = p.E827K on NM_020901.4) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52752013, COSV52753172; called by muse, mutect2, varscan2
- PLSCR1 | c.732T>G p.D244E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.192); catalogued as COSV61012350; called by muse, mutect2, varscan2
- SLC25A43 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54217184; called by muse, mutect2, varscan2
- TSGA10IP | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV73245218; called by muse, mutect2, varscan2
- YIF1A | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61012178; called by muse, mutect2, varscan2
- SYNRG | c.1142C>A p.P381Q | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDGFRB | c.1941C>A p.A647= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
